Gene-level copy-number profile of tumor specimen ALCH-AFDI-TTP1-A from ALCHEMIST case ALCH-AFDI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.1 years (21,939 days).
Specimen ALCH-AFDI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2b2d7cba-8a92-46e3-ac8c-3eb47ec7a795.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFDI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/ceac2b6d-2a5e-464f-8049-4e514b2a811c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 18,981; copy number 2: 33,592; copy number 3: 4,373; copy number 4: 1,377; copy number 5: 1; copy number 26: 5.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:65,419–133,723, 3 genes (within-gene range 0–3): OR4F5, AL627309.1, AL627309.3.
- chr2:119,156,243–119,170,115, 2 genes: C1QL2, RN7SL468P.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr8:8,228,595–8,244,865, 2 genes: FAM86B3P, ALG1L13P.
- chr15:73,730,048–73,752,747, 2 genes (within-gene range 0–2): AC022188.1, INSYN1.
- chr17:16,438,767–16,492,193, 6 genes (within-gene range 0–1): SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:18,415,728–18,551,705, 13 genes (within-gene range 0–1): KRT17P5, YWHAEP2, KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr17:20,449,395–20,467,539, 1 gene: LGALS9B.
- chr17:46,762,506–46,833,154, 1 gene: WNT3.
- chr17:61,354,763–61,485,110, 8 genes (within-gene range 0–1): AC005746.3, AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1.
- chr19:4,621,194–4,785,077, 9 genes: AC011498.5, TNFAIP8L1, MYDGF, AC005339.1, DPP9, DPP9-AS1, AC005594.1, MIR7-3HG, MIR7-3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:1,947,278–1,984,522, 1 gene, copy number 5 (within-gene range 2–5): MRPL23.
- chr11:1,991,096–2,001,470, 5 genes, copy number 26: LINC01219, H19, AC051649.3, MIR675, AC051649.2.

Autosomal genes at a single copy (total copy number 1): 17,411. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
